Somatic mutation profile of tumor specimen MP2PRT-PASZLP-TBP1-B (aliquot MP2PRT-PASZLP-TBP1-B-1-0-D-A83O-36) from MP2PRT case MP2PRT-PASZLP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 4.7 years (1,712 days).
Specimen MP2PRT-PASZLP-TBP1-B: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb6ec9fa-1595-45f1-8a5c-d2b6554372ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASZLP-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASZLP-NM1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a5bbc24-0600-4b03-a147-4118b258ad2a

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, Intron 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 35/562 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2
- SHOX | c.877T>C p.*293Rext*48 | Nonstop Mutation (SNP) | VAF 56/569 reads (10%) | catalogued as rs137852559, CM042778; ClinVar: pathogenic; called by muse, mutect2
- ANKRD13B | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 44/597 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as rs749795431, COSV101198964; called by muse, mutect2
- COL12A1 | c.2942G>C p.S981T | Missense Mutation (SNP) | VAF 36/484 reads (7%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.608); catalogued as COSV59395012; called by muse, mutect2
- NCBP2 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 44/586 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.35); catalogued as COSV58317775; called by muse, mutect2
- PKP1 | c.2237G>A p.R746Q | Missense Mutation (SNP) | VAF 23/344 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs1488332347, COSV55823393, COSV99825465; called by muse, mutect2
- PPP1R16A | c.310G>A p.G104S | Missense Mutation (SNP) | VAF 36/551 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs949445720; called by muse, mutect2
- ARAP3 | c.2677G>A p.A893T | Missense Mutation (SNP) | VAF 70/797 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2
- ANK1 | c.3039C>T p.N1013= | Silent (SNP) | VAF 34/513 reads (7%) | catalogued as rs111620878; called by muse, mutect2
- TAS1R3 | c.1806G>A p.S602= | Silent (SNP) | VAF 50/774 reads (6%) | catalogued as rs774961909, COSV100229689; called by muse, mutect2
- THBS2 | c.2058C>T p.G686= | Silent (SNP) | VAF 46/916 reads (5%) | catalogued as rs576041153; called by muse, mutect2
- TMTC1 | c.939-27496T>A | Intron (SNP) | VAF 20/221 reads (9%) | called by muse, mutect2
